Somatic mutation profile of tumor specimen TARGET-10-PAREAA-09A (aliquot TARGET-10-PAREAA-09A-01D) from TARGET case TARGET-10-PAREAA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,869 days).
Specimen TARGET-10-PAREAA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a1d0eca-8e75-40d2-8bda-12e4537bf9cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREAA-10A (Blood Derived Normal), aliquot TARGET-10-PAREAA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d984458f-5fea-4601-bbe4-e0dc825e0849

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'Flank 2, Frame Shift Ins 2, Nonsense Mutation 1, Silent 1, Frame Shift Del 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF3C1 | c.3349G>A p.A1117T | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs1377802104; called by muse, mutect2, varscan2
- PLXNA4 | c.3130C>T p.R1044W | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs773666064, COSV58108758; called by muse, mutect2
- TBL1X | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV54281095; called by mutect2, varscan2
- ZEB2 | c.3113A>G p.H1038R | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57953045; called by muse, mutect2, varscan2
- CARS1 | c.283_298delinsTTTCTCCCTCCC p.I95Ffs*38 | Frame Shift Del (DEL) | VAF 21/41 reads (51%) | called by muse*, pindel
- HCN4 | c.1694_1695insAGAGGCCCCGA p.D565Efs*13 | Frame Shift Ins (INS) | VAF 17/43 reads (40%) | called by mutect2, pindel, varscan2
- KIF26B | c.4357_4358insACTAACGG p.A1453Dfs*2 | Frame Shift Ins (INS) | VAF 15/48 reads (31%) | called by mutect2, pindel, varscan2
- THRAP3 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- EPB41L4A | c.108G>A p.T36= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as rs750688199, COSV54863080, COSV54879195; called by muse, mutect2, varscan2
- HDDC3 | c.*108T>G | 3'UTR (SNP) | VAF 13/30 reads (43%) | called by muse, varscan2
- KCNT2 | chr1:196608465 G>A | 5'Flank (SNP) | VAF 6/11 reads (55%) | catalogued as COSV54092148; called by muse, mutect2, varscan2
- NUSAP1 | chr15:41332831 G>T | 5'Flank (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- SGCA | c.983+1765C>T | Intron (SNP) | VAF 5/13 reads (38%) | catalogued as rs1002158074; called by muse, mutect2, varscan2
